Gene-level copy-number profile of tumor specimen TCGA-21-1080-01A from TCGA case TCGA-21-1080, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 66.4 years (24,253 days).
Specimen TCGA-21-1080-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.d4a48b3a-1120-4c9e-ab21-df1a0488ee0c.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-21-1080-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2f3a913f-a43f-408c-8f60-3b29e5169536

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 16,269; copy number 2: 38,550; copy number 3: 3,520; copy number 4: 692; copy number 5: 494; copy number 6: 251; copy number 7: 33; copy number 11: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-21-1080-01A-01D-0685-01): tumor purity 0.77, ploidy 1.88, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 780 genes in 11 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:189,631,389–198,222,513, 213 genes, copy number 5 (broad region; genes not listed).
- chr5:4,012,708–4,147,429, 3 genes, copy number 5: AC025773.1, AC025187.1, LINC02063.
- chr5:4,987,789–9,903,852, 96 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr5:13,690,331–29,217,115, 190 genes, copy number 6 (within-gene range 4–6) (broad region; genes not listed).
- chr5:50,396,192–52,959,209, 31 genes, copy number 6 (within-gene range 4–6): EMB, AC112187.2, AC112187.1, AC112187.3, PARP8, AC022441.1, AC022441.3, AC022441.2, AC008808.2, LINC02106, AC008808.1, RNU6-480P, AC091834.1, RNU6-1296P, AC026798.1, AC010478.1, ISL1, HMGB1P47, AC091860.1, AC022433.1, AC091860.2, RNA5SP182, KATNBL1P4, AC091903.1, LINC02118, RPS17P11, MFSD4BP1, AC022126.1, PELO, ITGA1, AC022133.2.
- chr5:55,219,564–56,382,075, 33 genes, copy number 7: MCIDAS, CCNO, AC026704.1, DHX29, MTREX, AC020728.1, PLPP1, AC010480.1, MIR5687, RNF138P1, AK4P2, SLC38A9, DDX4, AC016632.1, RNA5SP183, HNRNPH1P3, IL31RA, IL6ST, AC008914.1, AC016596.2, AC008892.1, FLJ31104, AC016596.1, ANKRD55, RNU6-299P, RPL17P22, RNA5SP184, C1GALT1P2, RNA5SP185, PSMC1P4, RNU6ATAC2P, AC034245.1, HMGN1P17.
- chr8:34,784,028–35,796,550, 7 genes, copy number 6: LINC01288, AC087343.1, AC099685.1, UNC5D, AC090740.1, LSM12P1, AC105230.1.
- chr9:32,293,558–33,039,907, 23 genes, copy number 6: RNA5SP281, SLC25A5P8, ACO1, DDX58, TOPORS, SMIM27, NDUFB6, DFFBP1, TAF1L, AL589642.1, AL589642.2, SNRPCP1, AL157884.1, TMEM215, Y_RNA, AL157884.3, AL157884.2, APTX, BOLA3P4, ASS1P12, TCEA1P4, LAGE3P1, DNAJA1.
- chr9:33,264,879–34,520,988, 61 genes, copy number 5 (broad region; genes not listed).
- chr19:44,326,555–46,471,563, 120 genes, copy number 5–11 (broad region; genes not listed).
- chr19:46,486,906–46,534,351, 3 genes, copy number 5: PNMA8B, AC011484.1, AC011551.1.

Autosomal genes at a single copy (total copy number 1): 13,882. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
